Somatic mutation profile of tumor specimen TCGA-56-7223-01A (aliquot TCGA-56-7223-01A-11D-2042-08) from TCGA case TCGA-56-7223, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 66.5 years (24,288 days).
Specimen TCGA-56-7223-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 132e790a-3e63-4045-838a-26e598cdcfb7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-56-7223-10A (Blood Derived Normal), aliquot TCGA-56-7223-10A-01D-2042-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea28dcbd-db43-461b-b607-472060767145

The open-access MAF lists 328 somatic variants for this specimen: 240 protein-altering or splice-affecting, 77 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 208, Silent 77, Splice Site 11, Nonsense Mutation 11, RNA 7, Frame Shift Del 6, Splice Region 2, Intron 2, 5'Flank 2, Frame Shift Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.527G>T p.C176F | Missense Mutation (SNP) | VAF 46/52 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A4GNT | c.729G>C p.E243D | Missense Mutation (SNP) | VAF 76/138 reads (55%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as COSV99367652; called by muse, mutect2, varscan2
- AASDHPPT | c.449G>C p.R150T | Missense Mutation (SNP) | VAF 56/64 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV53788482, COSV99593144; called by muse, mutect2, varscan2
- ABCC9 | c.1938G>T p.Q646H | Missense Mutation (SNP) | VAF 49/92 reads (53%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV53985016; called by muse, mutect2, varscan2
- ABRACL | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.352); catalogued as COSV100866310; called by muse, mutect2, varscan2
- AC004832.3 | c.611T>C p.F204S | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99840708; called by muse, mutect2, varscan2
- ADA | c.34G>A p.V12M | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65740099; called by muse, mutect2, varscan2
- ADAM22 | c.2036G>T p.C679F | Missense Mutation (SNP) | VAF 49/85 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99715387; called by muse, mutect2, varscan2
- ADCY6 | c.1889G>C p.R630P | Missense Mutation (SNP) | VAF 54/88 reads (61%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100326363; called by muse, mutect2, varscan2
- AHNAK2 | c.7258C>T p.Q2420* | Nonsense Mutation (SNP) | VAF 90/288 reads (31%) | catalogued as COSV100315011; called by muse, mutect2, varscan2
- ALOX5 | c.1300G>A p.V434M | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as rs554154845, COSV65551484; called by muse, mutect2, varscan2
- ANAPC2 | c.1168G>T p.G390C | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100118817; called by muse, mutect2, varscan2
- ANO3 | c.1117G>T p.G373* | Nonsense Mutation (SNP) | VAF 9/25 reads (36%) | catalogued as COSV99879789; called by muse, mutect2, varscan2
- AP002512.3 | c.952C>G p.L318V | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.792); catalogued as rs1374055633, COSV54405649, COSV99688163; called by muse, varscan2
- ARMC6 | c.254A>G p.Q85R (on ENST00000392336; = p.Q60R on NM_033415.4) | Missense Mutation (SNP) | VAF 64/73 reads (88%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as COSV99522876; called by muse, mutect2, varscan2
- ASXL1 | c.2935G>C p.D979H | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.031); catalogued as COSV100037305; called by muse, mutect2, varscan2
- ATP11B | c.1910C>T p.S637L | Missense Mutation (SNP) | VAF 118/653 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV100017419; called by muse, varscan2
- AZGP1 | c.256G>C p.D86H | Missense Mutation (SNP) | VAF 79/168 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV99447565; called by muse, mutect2, varscan2
- B3GNT4 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 75/186 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs762842306, COSV57336727, COSV99927964; called by muse, mutect2, varscan2
- BCAN | c.2155T>A p.Y719N | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV100227794; called by muse, mutect2, varscan2
- BCHE | c.1516G>A p.G506R | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100011908; called by muse, mutect2, varscan2
- C2orf78 | c.2255C>A p.A752D | Missense Mutation (SNP) | VAF 51/204 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); catalogued as COSV101280886; called by muse, mutect2, varscan2
- C6 | c.640A>G p.T214A | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.175); catalogued as COSV99666206; called by muse, mutect2, varscan2
- C8B | c.1673C>T p.S558F | Missense Mutation (SNP) | VAF 30/37 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1323143026, COSV100980659; called by muse, mutect2, varscan2
- CACNA1B | c.928T>C p.C310R | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99494473; called by muse, mutect2, varscan2
- CADPS2 | c.2286C>T p.F762= | Splice Region (SNP) | VAF 16/31 reads (52%) | catalogued as COSV100460257; called by muse, mutect2, varscan2
- CATSPER4 | c.87G>C p.M29I | Missense Mutation (SNP) | VAF 25/28 reads (89%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.007); catalogued as COSV100128155; called by muse, mutect2, varscan2
- CENPN | c.438G>C p.Q146H | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.999); catalogued as rs773404080, COSV100001028; called by muse, mutect2, varscan2
- CEP350 | c.8822G>A p.G2941D | Missense Mutation (SNP) | VAF 40/68 reads (59%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.977); catalogued as COSV100854218; called by muse, mutect2, varscan2
- CES5A | c.254G>T p.R85L | Missense Mutation (SNP) | VAF 46/83 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as COSV99306979; called by muse, mutect2, varscan2
- CFAP91 | c.231C>A p.F77L | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV99846759; called by muse, mutect2, varscan2
- CHL1 | c.1760G>T p.G587V (on ENST00000397491 / NM_001253387.1; = p.G603V on NM_006614.4) | Missense Mutation (SNP) | VAF 19/21 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99849698; called by muse, mutect2, varscan2
- CHPF | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.681); catalogued as rs372457597; called by muse, mutect2, varscan2
- CHRM3 | c.353G>T p.G118V | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55085005, COSV99697190; called by muse, mutect2
- CILP2 | c.2746G>A p.E916K | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99364205; called by muse, mutect2, varscan2
- CLCN1 | c.2440G>T p.V814F | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV100577582; called by muse, mutect2, varscan2
- CMYA5 | c.6871A>C p.K2291Q | Missense Mutation (SNP) | VAF 59/69 reads (86%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.131); catalogued as COSV101483713; called by muse, mutect2, varscan2
- CNTFR | c.740G>T p.R247L | Missense Mutation (SNP) | VAF 14/15 reads (93%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100667389; called by muse, mutect2, varscan2
- CNTNAP5 | c.2742G>T p.L914F | Missense Mutation (SNP) | VAF 48/161 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV101442886; called by muse, mutect2, varscan2
- COL1A2 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.72); catalogued as COSV99798120; called by muse, mutect2, varscan2
- COL4A2 | c.5024G>A p.W1675* | Nonsense Mutation (SNP) | VAF 27/83 reads (33%) | catalogued as COSV100847060; called by muse, mutect2, varscan2
- CR2 | c.1903A>T p.T635S | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.731); catalogued as COSV100889500, COSV65507517; called by muse, mutect2, varscan2
- CSMD2 | c.679G>T p.D227Y | Missense Mutation (SNP) | VAF 42/46 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99584434; called by muse, mutect2, varscan2
- CSMD3 | c.7714C>G p.P2572A (on ENST00000297405 / NM_001363185.1; = p.P2468A on NM_052900.3) | Missense Mutation (SNP) | VAF 58/66 reads (88%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99820889; called by muse, mutect2, varscan2
- CSNK1A1 | c.233G>A p.W78* | Nonsense Mutation (SNP) | VAF 23/29 reads (79%) | catalogued as COSV99939237; called by muse, mutect2, varscan2
- CTNND1 | c.793G>A p.V265I | Missense Mutation (SNP) | VAF 161/179 reads (90%) | SIFT tolerated (0.43); PolyPhen benign (0.065); catalogued as COSV100649701; called by muse, mutect2, varscan2
- CUL3 | c.1378-1G>A p.X460_splice | Splice Site (SNP) | VAF 98/164 reads (60%) | catalogued as COSV52362106, COSV52363563; called by muse, mutect2, varscan2
- CUL3 | c.227G>T p.G76V | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100023525; called by muse, mutect2, varscan2
- DISP2 | c.581C>A p.P194H | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99139638; called by muse, mutect2, varscan2
- DLD | c.67G>A p.G23S | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.003); catalogued as COSV99226705; called by muse, mutect2, varscan2
- DLG1 | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 25/483 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.56); catalogued as rs762105289, COSV100014429; called by muse, mutect2
- DLX4 | c.500A>T p.N167I (on ENST00000240306 / NM_138281.3; = p.N95I on NM_001934.3) | Missense Mutation (SNP) | VAF 102/475 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99537394; called by muse, mutect2, varscan2
- DMXL1 | c.8609C>T p.T2870I | Missense Mutation (SNP) | VAF 43/53 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100222953, COSV60719838; called by muse, mutect2, varscan2
- DNAH11 | c.11261A>T p.Q3754L | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as COSV100176174; called by muse, mutect2, varscan2
- DNAH2 | c.1679G>T p.R560I | Missense Mutation (SNP) | VAF 46/58 reads (79%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.625); catalogued as COSV50018006, COSV99317792; called by muse, mutect2, varscan2
- DNAH9 | c.2175G>T p.M725I | Missense Mutation (SNP) | VAF 90/103 reads (87%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV99303141; called by muse, mutect2, varscan2
- DNAJC2 | c.404A>C p.N135T | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99971545; called by muse, mutect2, varscan2
- DPPA2 | c.855-1G>A p.X285_splice | Splice Site (SNP) | VAF 58/181 reads (32%) | catalogued as COSV101524726; called by muse, mutect2, varscan2
- DPY19L1 | c.1963A>T p.K655* | Nonsense Mutation (SNP) | VAF 37/77 reads (48%) | catalogued as rs1262474717, COSV100204392; called by muse, mutect2, varscan2
- DUSP13 | c.288C>A p.H96Q | Missense Mutation (SNP) | VAF 21/25 reads (84%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.509); catalogued as COSV100403224; called by muse, mutect2, varscan2
- EMC3 | c.495-2A>T p.X165_splice | Splice Site (SNP) | VAF 46/48 reads (96%) | catalogued as COSV99793835; called by muse, mutect2, varscan2
- EPB41L5 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1411700602, COSV55350609; called by muse, mutect2, varscan2
- EPRS1 | c.4406C>T p.P1469L | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.147); catalogued as rs1239307023, COSV100859254; called by muse, mutect2, varscan2
- ESYT3 | c.2081G>T p.G694V | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.916); catalogued as COSV101272612; called by muse, mutect2, varscan2
- FAM160A2 | c.820C>T p.R274* | Nonsense Mutation (SNP) | VAF 55/182 reads (30%) | catalogued as rs1244727701, COSV56415065; called by muse, mutect2, varscan2
- FLNC | c.1672C>A p.R558S | Missense Mutation (SNP) | VAF 93/207 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.73); catalogued as COSV100367478, COSV57962044; called by muse, mutect2, varscan2
- FN1 | c.1666G>A p.D556N | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100115471; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.073); catalogued as rs201470572, COSV58547803; called by muse, mutect2, varscan2
- FREM2 | c.2002G>T p.D668Y | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV104382623, COSV99746095; called by muse, mutect2, varscan2
- FRMPD4 | c.1370T>C p.L457P | Missense Mutation (SNP) | VAF 88/91 reads (97%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV101041875, COSV101042660; called by muse, mutect2, varscan2
- FSTL1 | c.303G>T p.K101N | Missense Mutation (SNP) | VAF 53/149 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.796); catalogued as COSV99820409; called by muse, mutect2, varscan2
- FTSJ3 | c.191A>C p.K64T | Missense Mutation (SNP) | VAF 80/424 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV100037107; called by muse, mutect2, varscan2
- GABRA5 | c.714C>A p.S238R | Missense Mutation (SNP) | VAF 24/34 reads (71%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as COSV100164630; called by muse, mutect2, varscan2
- GALNT17 | c.1093G>C p.G365R | Missense Mutation (SNP) | VAF 66/174 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100351740; called by muse, mutect2, varscan2
- GCN1 | c.7597G>T p.G2533C | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100324480; called by muse, mutect2, varscan2
- GCN1 | c.7596G>C p.M2532I | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV100324481; called by muse, mutect2, varscan2
- GOLGB1 | c.7062C>G p.F2354L | Missense Mutation (SNP) | VAF 59/129 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.061); catalogued as COSV100510184, COSV61473000; called by muse, mutect2, varscan2
- GPR101 | c.227C>A p.T76N | Missense Mutation (SNP) | VAF 66/66 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV53240086, COSV99981201; called by muse, mutect2, varscan2
- GPR150 | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 35/38 reads (92%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as COSV101187369; called by muse, mutect2, varscan2
- GPX6 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100724724; called by muse, mutect2, varscan2
- GRIN2A | c.3877G>T p.D1293Y | Missense Mutation (SNP) | VAF 72/129 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778230379, COSV100407538, COSV58019424; called by muse, mutect2, varscan2
- GRK4 | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs754105109, COSV100583773; called by muse, mutect2, varscan2
- GSG1L | c.919G>A p.D307N (on ENST00000447459 / NM_001109763.2; = p.D152N on NM_144675.2) | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.191); catalogued as COSV101093365; called by muse, mutect2, varscan2
- GSKIP | c.247G>C p.A83P | Missense Mutation (SNP) | VAF 33/42 reads (79%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.843); catalogued as rs755731284, COSV101347608; called by muse, mutect2, varscan2
- GYG1 | c.604A>G p.K202E | Missense Mutation (SNP) | VAF 95/248 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV99936661; called by muse, mutect2, varscan2
- HCN1 | c.2113A>T p.S705C | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.887); catalogued as COSV100297780; called by muse, mutect2, varscan2
- HGF | c.2123G>T p.R708L | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV55956695, COSV99735158; called by muse, mutect2, varscan2
- HGSNAT | c.928T>A p.L310M | Missense Mutation (SNP) | VAF 97/103 reads (94%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV99925016; called by muse, mutect2, varscan2
- HK3 | c.2015G>A p.G672D | Missense Mutation (SNP) | VAF 110/120 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99457577; called by muse, mutect2, varscan2
- HLX | c.1019A>C p.Q340P | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as COSV100854425; called by muse, mutect2, varscan2
- HOXB5 | c.474G>T p.Q158H | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.276); catalogued as rs1344574133, COSV99494311; called by muse, mutect2, varscan2
- HOXD4 | c.154T>A p.Y52N | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV100106518; called by muse, mutect2, varscan2
- HOXD9 | c.35C>G p.S12C | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99981629; called by muse, mutect2, varscan2
- HTR1E | c.917C>G p.P306R | Missense Mutation (SNP) | VAF 111/203 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100540833; called by muse, mutect2, varscan2
- HTR2A | c.122A>G p.D41G | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.015); catalogued as COSV101096526; called by muse, mutect2, varscan2
- IFT57 | c.758C>T p.T253M | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as rs774931041, COSV52711861; called by muse, mutect2, varscan2
- IGHV4-31 | c.64C>A p.Q22K | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.048); catalogued as rs754985489; called by muse, mutect2, varscan2
- IGKV1-6 | c.112G>A p.G38R | Missense Mutation (SNP) | VAF 83/283 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.705); catalogued as rs374818034; called by muse, mutect2, varscan2
- IL4I1 | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 29/30 reads (97%) | SIFT tolerated (0.57); PolyPhen benign (0.013); catalogued as rs1251045975, COSV55578636; called by muse, mutect2, varscan2
- ILDR2 | c.1902G>T p.R634S | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99613010; called by muse, mutect2, varscan2
- IMPG1 | c.1250C>G p.P417R | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as COSV100885721, COSV64062524, COSV64062578; called by muse, mutect2, varscan2
- INSIG2 | c.274G>C p.D92H | Missense Mutation (SNP) | VAF 84/148 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99830365; called by muse, mutect2, varscan2
- ITFG2 | c.289C>A p.P97T | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.036); catalogued as COSV99957945, COSV99958264; called by muse, mutect2, varscan2
- ITGA7 | c.1774C>A p.R592S (on ENST00000555728; = p.R548S on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as COSV57697061, COSV99144133; called by muse, mutect2, varscan2
- ITIH5 | c.2173A>G p.I725V | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.105); catalogued as COSV99903349; called by muse, mutect2, varscan2
- KAT7 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.402); catalogued as rs1249332159, COSV99371544; called by muse, mutect2, varscan2
- KCNK2 | c.769A>G p.I257V (on ENST00000444842 / NM_001017425.3; = p.I242V on NM_014217.4) | Missense Mutation (SNP) | VAF 64/144 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.11); catalogued as COSV101221732; called by muse, mutect2, varscan2
- KCNK3 | c.149C>A p.A50E | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as rs1427745758, COSV100256563; called by mutect2, varscan2
- KCNQ5 | c.502A>T p.I168F | Missense Mutation (SNP) | VAF 115/204 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100570813; called by muse, mutect2, varscan2
- KCTD16 | c.246C>A p.F82L | Missense Mutation (SNP) | VAF 31/34 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101568682, COSV72576916; called by muse, mutect2, varscan2
- KIAA1109 | c.9319C>G p.L3107V | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99145353; called by muse, mutect2, varscan2
- KIF13A | c.114C>A p.H38Q | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as COSV99433184; called by muse, mutect2, varscan2
- KIF26A | c.542G>T p.G181V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as COSV100180612; called by muse, mutect2, varscan2
- KIF26A | c.3451G>A p.G1151S | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59467633; called by muse, mutect2, varscan2
- KIR2DL3 | c.730C>A p.L244M | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs371328407; called by muse, varscan2
- KLC4 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV99431159; called by muse, mutect2, varscan2
- KPRP | c.1354C>A p.P452T | Missense Mutation (SNP) | VAF 114/266 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV100908642; called by muse, mutect2, varscan2
- L1CAM | c.1573C>A p.R525S | Missense Mutation (SNP) | VAF 136/147 reads (93%) | SIFT tolerated (0.18); PolyPhen benign (0.058); catalogued as COSV100648815; called by muse, mutect2, varscan2
- LRRIQ4 | c.1243G>T p.V415L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.077); catalogued as COSV61618550; called by muse, mutect2, varscan2
- LTBP3 | c.2182A>G p.I728V | Missense Mutation (SNP) | VAF 51/60 reads (85%) | SIFT tolerated (1); PolyPhen benign (0.09); catalogued as COSV100098754; called by muse, mutect2, varscan2
- MED14 | c.1490A>T p.K497M | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV100247232; called by muse, mutect2, varscan2
- MEGF11 | c.1178C>G p.S393C | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99986648; called by muse, mutect2, varscan2
- MELTF | c.642C>T p.F214= | Splice Region (SNP) | VAF 171/691 reads (25%) | catalogued as COSV99585667; called by muse, mutect2, varscan2
- METTL21C | c.509T>C p.L170P | Missense Mutation (SNP) | VAF 35/56 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99939930; called by muse, mutect2, varscan2
- MINAR1 | c.2038G>T p.D680Y | Missense Mutation (SNP) | VAF 65/197 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV100548547; called by muse, mutect2, varscan2
- MPEG1 | c.1021T>A p.Y341N | Missense Mutation (SNP) | VAF 61/69 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57088318, COSV99914860; called by muse, mutect2, varscan2
- MPLKIP | c.401A>G p.N134S | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as COSV99999032; called by muse, mutect2
- MUC5B | c.7711C>G p.P2571A | Missense Mutation (SNP) | VAF 67/278 reads (24%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.157); catalogued as COSV101499943; called by muse, mutect2, varscan2
- MUC5B | c.10907G>T p.C3636F | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101499944; called by muse, mutect2, varscan2
- MYBPC2 | c.1123C>T p.Q375* | Nonsense Mutation (SNP) | VAF 52/227 reads (23%) | catalogued as COSV63094127; called by muse, mutect2, varscan2
- MYT1L | c.955G>A p.D319N | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.871); catalogued as rs1219261934, COSV67711546; called by muse, mutect2, varscan2
- NAV3 | c.5782C>T p.R1928* (on ENST00000397909 / NM_001024383.2; = p.R1906* on NM_014903.6) | Nonsense Mutation (SNP) | VAF 18/42 reads (43%) | catalogued as COSV57077561; called by muse, mutect2, varscan2
- NPAS2 | c.267G>T p.M89I | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV100175585; called by muse, mutect2, varscan2
- NPAS2 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV100175586; called by muse, mutect2, varscan2
- NPC1L1 | c.2014G>T p.G672W | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM068042, COSV99202550; called by muse, mutect2, varscan2
- NPNT | c.239G>T p.G80V | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1418226046, COSV99974609; called by muse, mutect2, varscan2
- NPTX1 | c.330G>T p.Q110H | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.276); catalogued as COSV100150811; called by muse, mutect2, varscan2
- NUP155 | c.2482A>C p.I828L (on ENST00000231498 / NM_153485.3; = p.I769L on NM_004298.4) | Missense Mutation (SNP) | VAF 60/100 reads (60%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as COSV99192132; called by muse, mutect2, varscan2
- OR2L3 | c.240G>T p.M80I | Missense Mutation (SNP) | VAF 157/372 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100741887; called by muse, mutect2, varscan2
- OR2M2 | c.103T>A p.F35I | Missense Mutation (SNP) | VAF 219/440 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as rs754995992, COSV62897952; called by muse, mutect2, varscan2
- OR2M5 | c.87T>A p.F29L | Missense Mutation (SNP) | VAF 250/457 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as COSV100822704; called by muse, mutect2, varscan2
- OR4C12 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 31/35 reads (89%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.739); catalogued as rs1555020035, COSV100078107; called by muse, mutect2
- OR51E1 | c.35C>A p.A12D | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.588); catalogued as COSV101211439; called by muse, mutect2, varscan2
- OSBPL5 | c.2014G>C p.A672P | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.436); catalogued as COSV99719865; called by muse, mutect2, varscan2
- OTOL1 | c.250C>G p.L84V | Missense Mutation (SNP) | VAF 100/244 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.223); catalogued as COSV100019685; called by muse, mutect2, varscan2
- P3H1 | c.1881_1882del p.F627Lfs*4 | Frame Shift Del (DEL) | VAF 120/176 reads (68%) | catalogued as rs769409112; called by mutect2, pindel, varscan2
- PASK | c.1304A>T p.Q435L | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs756535845, COSV99298425; called by muse, mutect2, varscan2
- PCDH10 | c.2658C>G p.S886R | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.79); PolyPhen benign (0.23); catalogued as COSV99992629; called by muse, mutect2, varscan2
- PCP4 | c.130G>T p.V44L | Missense Mutation (SNP) | VAF 45/52 reads (87%) | SIFT tolerated (0.35); PolyPhen benign (0.027); catalogued as rs776961140, COSV100150479, COSV60789292; called by muse, mutect2, varscan2
- PCSK2 | c.882C>A p.N294K | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.055); catalogued as COSV52738571; called by muse, varscan2
- PDK4 | c.601G>T p.V201L | Missense Mutation (SNP) | VAF 76/191 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV99138700; called by muse, mutect2, varscan2
- PEX1 | c.94C>G p.P32A | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV99720003; called by muse, mutect2, varscan2
- PIKFYVE | c.2191G>A p.E731K | Missense Mutation (SNP) | VAF 50/96 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100009494; called by muse, mutect2, varscan2
- PILRA | c.548G>C p.G183A | Missense Mutation (SNP) | VAF 56/117 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as COSV99546237; called by muse, mutect2, varscan2
- PKD2L1 | c.800G>A p.G267E | Missense Mutation (SNP) | VAF 43/50 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100559237; called by muse, mutect2, varscan2
- PLAU | c.974A>G p.D325G | Missense Mutation (SNP) | VAF 72/87 reads (83%) | SIFT tolerated (0.07); PolyPhen benign (0.287); catalogued as COSV101032204; called by muse, mutect2, varscan2
- PLCG2 | c.1936T>G p.W646G | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV100842001; called by muse, mutect2, varscan2
- PNPLA3 | c.359G>A p.R120K | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99336864; called by muse, mutect2
- PPIE | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV60971545; called by muse, mutect2, varscan2
- PPP1R15B | c.1385C>T p.S462L | Missense Mutation (SNP) | VAF 82/179 reads (46%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.477); catalogued as COSV100916288; called by muse, mutect2, varscan2
- PRDM11 | c.596A>G p.D199G (on ENST00000530656 / NM_001359633.1; = p.D165G on NM_001256695.1) | Missense Mutation (SNP) | VAF 70/114 reads (61%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as COSV99770216; called by muse, mutect2, varscan2
- PRDM7 | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 61/243 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.285); catalogued as COSV101344484; called by muse, mutect2, varscan2
- PRKG2 | c.1353G>T p.Q451H | Missense Mutation (SNP) | VAF 75/159 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV100019086; called by muse, mutect2, varscan2
- PTPRM | c.2435A>T p.H812L | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100154080; called by muse, mutect2, varscan2
- PTPRZ1 | c.5015A>G p.Y1672C | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101099257; called by muse, mutect2, varscan2
- PTX3 | c.754G>C p.E252Q | Missense Mutation (SNP) | VAF 115/241 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.645); catalogued as COSV99904741; called by muse, mutect2, varscan2
- PTX3 | c.801G>C p.W267C | Missense Mutation (SNP) | VAF 134/243 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99904744; called by muse, mutect2, varscan2
- PTX3 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 135/273 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV99904747; called by muse, mutect2, varscan2
- RANBP17 | c.2455A>G p.K819E | Missense Mutation (SNP) | VAF 147/160 reads (92%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs1476854530, COSV66658040; called by muse, mutect2, varscan2
- RASAL2 | c.1622G>T p.W541L | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100862235; called by muse, mutect2, varscan2
- RASGRF1 | c.2869G>A p.V957M | Missense Mutation (SNP) | VAF 66/77 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs781552482, COSV101174231; called by muse, mutect2, varscan2
- RASGRF2 | c.2857G>C p.D953H | Missense Mutation (SNP) | VAF 66/80 reads (83%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV99428282; called by muse, mutect2, varscan2
- RFPL2 | c.401G>T p.G134V | Missense Mutation (SNP) | VAF 60/94 reads (64%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99963926; called by muse, mutect2, varscan2
- RFPL2 | c.157G>A p.V53M | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.19); catalogued as rs1383352202, COSV99963928; called by muse, mutect2, varscan2
- RGS18 | c.437A>G p.D146G | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV100817632; called by muse, mutect2, varscan2
- ROCK1 | c.175+1G>A p.X59_splice | Splice Site (SNP) | VAF 9/11 reads (82%) | catalogued as COSV101296203; called by muse, mutect2, varscan2
- ROS1 | c.70G>T p.V24L | Missense Mutation (SNP) | VAF 45/78 reads (58%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV100876056; called by muse, mutect2, varscan2
- RRH | c.720+1G>A p.X240_splice | Splice Site (SNP) | VAF 5/11 reads (45%) | catalogued as COSV100495920; called by muse, mutect2, varscan2
- RXFP3 | c.461T>C p.M154T | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.896); catalogued as rs1231454057, COSV100347159; called by muse, mutect2, varscan2
- RXRB | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.913); catalogued as COSV100807537; called by muse, mutect2, varscan2
- SAT2 | c.67-1G>C p.X23_splice | Splice Site (SNP) | VAF 48/54 reads (89%) | catalogued as COSV99352058; called by muse, mutect2, varscan2
- SCAF8 | c.1096A>G p.I366V | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.049); catalogued as rs986195224, COSV100913842; called by muse, mutect2, varscan2
- SCN4A | c.2029T>C p.F677L | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as COSV101438277; called by muse, mutect2, varscan2
- SCN9A | c.659G>T p.R220I | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100310838, COSV100312195; called by muse, mutect2, varscan2
- SETD2 | c.4781A>G p.K1594R | Missense Mutation (SNP) | VAF 61/67 reads (91%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV100337733; called by muse, mutect2, varscan2
- SHC2 | c.1467C>A p.H489Q | Missense Mutation (SNP) | VAF 19/20 reads (95%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.996); catalogued as COSV99198898; called by muse, mutect2, varscan2
- SLC16A14 | c.703G>C p.E235Q | Missense Mutation (SNP) | VAF 64/189 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.664); catalogued as COSV99725074; called by muse, mutect2, varscan2
- SLC22A9 | c.1541T>G p.L514R | Missense Mutation (SNP) | VAF 52/60 reads (87%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as COSV99654615; called by muse, mutect2, varscan2
- SLC26A7 | c.73A>G p.I25V | Missense Mutation (SNP) | VAF 44/47 reads (94%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1371197122, COSV52592892; called by muse, mutect2, varscan2
- SLC35F4 | c.323C>T p.A108V (on ENST00000339762 / NM_001352015.2; = p.A72V on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV100333406; called by muse, mutect2, varscan2
- SLCO2B1 | c.17-2A>G p.X6_splice | Splice Site (SNP) | VAF 103/270 reads (38%) | catalogued as COSV99214116; called by muse, mutect2, varscan2
- SLIT2 | c.2601G>T p.M867I | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as COSV99879830; called by muse, mutect2, varscan2
- SLITRK3 | c.739C>G p.L247V | Missense Mutation (SNP) | VAF 56/147 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99578178; called by muse, mutect2, varscan2
- SLITRK5 | c.2651C>A p.P884H | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT tolerated (0.77); PolyPhen benign (0.07); catalogued as COSV100280088; called by muse, mutect2, varscan2
- SMAD1 | c.272T>C p.V91A | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV57472228; called by muse, mutect2, varscan2
- SPTB | c.652G>T p.D218Y | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101071865; called by muse, mutect2, varscan2
- ST18 | c.82C>G p.L28V | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.333); catalogued as COSV99387716; called by muse, mutect2, varscan2
- STXBP5L | c.1232C>T p.P411L | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99871460; called by muse, mutect2, varscan2
- SWT1 | c.599A>G p.K200R | Missense Mutation (SNP) | VAF 44/81 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV100832968; called by muse, mutect2, varscan2
- TAS2R60 | c.19G>T p.V7F | Missense Mutation (SNP) | VAF 82/221 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.421); catalogued as COSV100223427; called by muse, mutect2, varscan2
- TCERG1 | c.2735G>C p.R912P | Missense Mutation (SNP) | VAF 59/109 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99694277; called by muse, mutect2, varscan2
- TCN2 | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 60/110 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99308326; called by muse, mutect2, varscan2
- TLR3 | c.1696A>G p.I566V | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV99710734; called by muse, mutect2, varscan2
- TMED6 | c.378C>A p.H126Q | Missense Mutation (SNP) | VAF 52/161 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as COSV99650577; called by muse, mutect2, varscan2
- TMEM255B | c.248A>G p.Q83R | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as rs1043917638, COSV100943053; called by muse, mutect2, varscan2
- TPH2 | c.952C>A p.H318N | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100421802; called by muse, mutect2, varscan2
- TPTE2 | c.1369G>T p.D457Y (on ENST00000400230 / NM_199254.2; = p.D380Y on NM_130785.3) | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55017423, COSV99689461; called by muse, varscan2
- TRAK1 | c.1804G>A p.D602N (on ENST00000327628 / NM_001349247.2; = p.D544N on NM_014965.5) | Missense Mutation (SNP) | VAF 68/84 reads (81%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100409673; called by muse, mutect2, varscan2
- TRIO | c.4778G>A p.R1593Q | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.833); catalogued as rs1404663085, COSV100709598; called by muse, mutect2, varscan2
- TRPC5 | c.22A>G p.K8E | Missense Mutation (SNP) | VAF 20/22 reads (91%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.472); catalogued as COSV99458961; called by muse, mutect2, varscan2
- TSC22D3 | c.10G>T p.E4* | Nonsense Mutation (SNP) | VAF 8/47 reads (17%) | catalogued as COSV100226624; called by muse, mutect2, varscan2
- UBE2E3 | c.389G>T p.R130L | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.927); catalogued as COSV101150106; called by muse, mutect2, varscan2
- UEVLD | c.128-2A>T p.X43_splice | Splice Site (SNP) | VAF 8/44 reads (18%) | catalogued as rs751386957, COSV100260728; called by muse, varscan2
- UGGT1 | c.696+1G>T p.X232_splice | Splice Site (SNP) | VAF 9/34 reads (26%) | catalogued as COSV99390094; called by muse, varscan2
- UGT2A1 | c.443T>G p.V148G | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV99683662; called by muse, mutect2, varscan2
- UMOD | c.1364T>G p.M455R | Missense Mutation (SNP) | VAF 34/55 reads (62%) | SIFT tolerated (0.47); PolyPhen benign (0.158); catalogued as COSV100207891; called by muse, mutect2, varscan2
- UROC1 | c.737C>A p.T246N | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99330621; called by muse, mutect2, varscan2
- USF3 | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs551361456, COSV100324604; called by muse, mutect2, varscan2
- VPS13D | c.1077G>T p.K359N | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as COSV100691983; called by muse, mutect2, varscan2
- WDR61 | c.371G>A p.G124E | Missense Mutation (SNP) | VAF 15/16 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99144512; called by muse, mutect2, varscan2
- ZBED1 | c.1230G>T p.M410I | Missense Mutation (SNP) | VAF 52/56 reads (93%) | SIFT tolerated (0.27); PolyPhen benign (0.062); catalogued as COSV100585107; called by muse, mutect2, varscan2
- ZBTB46 | c.955A>T p.T319S | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV99828609; called by muse, mutect2, varscan2
- ZIC4 | c.463G>A p.V155I | Missense Mutation (SNP) | VAF 58/300 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs749529573, COSV101267778; called by muse, mutect2, varscan2
- ZMYM4 | c.670-2A>G p.X224_splice | Splice Site (SNP) | VAF 5/18 reads (28%) | catalogued as COSV100109236; called by muse, mutect2, varscan2
- ZNF382 | c.1629G>T p.K543N | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as COSV99497260; called by muse, mutect2, varscan2
- ZNF521 | c.914G>C p.S305T | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV100831282; called by muse, mutect2, varscan2
- ZNF80 | c.405C>A p.C135* | Nonsense Mutation (SNP) | VAF 29/123 reads (24%) | catalogued as COSV100351880; called by muse, mutect2, varscan2
- ZNF804B | c.1582C>A p.Q528K | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as COSV100301216; called by muse, mutect2, varscan2
- ZNF804B | c.1895C>A p.S632Y | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV100301218; called by muse, mutect2, varscan2
- ZNF831 | c.3016G>C p.E1006Q | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV100925698; called by muse, mutect2, varscan2
- ZNF835 | c.253G>T p.A85S | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.026); catalogued as COSV101606233, COSV73379348; called by muse, mutect2, varscan2
- ANKRD50 | c.239dup p.S81Qfs*9 | Frame Shift Ins (INS) | VAF 20/63 reads (32%) | called by mutect2, pindel, varscan2
- CLDN12 | c.727_728del p.T243Hfs*6 | Frame Shift Del (DEL) | VAF 46/136 reads (34%) | called by pindel, varscan2
- COG6 | c.624-1G>A p.X208_splice | Splice Site (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2, varscan2
- COP1 | c.984del p.T329Qfs*25 | Frame Shift Del (DEL) | VAF 69/224 reads (31%) | called by mutect2, pindel, varscan2
- FAM155B | c.494del p.P165Lfs*60 | Frame Shift Del (DEL) | VAF 23/32 reads (72%) | called by mutect2, pindel, varscan2
- IGHD2-21 | c.11G>C p.W4S | Missense Mutation (SNP) | VAF 12/37 reads (32%) | called by muse, mutect2, varscan2
- NEGR1 | c.658del p.V220Lfs*16 | Frame Shift Del (DEL) | VAF 34/51 reads (67%) | called by mutect2, pindel, varscan2
- SSU72P8 | c.337G>T p.E113* | Nonsense Mutation (SNP) | VAF 37/63 reads (59%) | called by muse, mutect2, varscan2
- SYT13 | c.668del p.E223Gfs*17 | Frame Shift Del (DEL) | VAF 29/113 reads (26%) | called by mutect2, pindel, varscan2
- ACTL9 | c.924G>A p.P308= | Silent (SNP) | VAF 29/69 reads (42%) | catalogued as rs782169532, COSV100185055; called by muse, mutect2, varscan2
- ADAMTS3 | c.1887C>T p.T629= | Silent (SNP) | VAF 40/103 reads (39%) | catalogued as COSV99709936; called by muse, mutect2, varscan2
- ADGRG7 | c.2256G>A p.R752= | Silent (SNP) | VAF 18/113 reads (16%) | catalogued as COSV99840392; called by muse, mutect2, varscan2
- AFAP1L2 | c.2358T>C p.S786= (on ENST00000304129 / NM_001351075.1; = p.S782= on NM_032550.3 and 11 other RefSeq transcripts) | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as COSV100412065; called by muse, mutect2, varscan2
- ALAD | c.711T>C p.A237= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV99474472; called by muse, mutect2, varscan2
- ATP10D | c.1644C>T p.D548= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as rs760347995, COSV56708656; called by muse, mutect2, varscan2
- ATP12A | c.1101C>A p.A367= | Silent (SNP) | VAF 14/103 reads (14%) | catalogued as COSV99516773; called by muse, mutect2, varscan2
- ATP13A4 | c.636C>T p.F212= | Silent (SNP) | VAF 16/158 reads (10%) | catalogued as COSV99793899; called by muse, mutect2
- BAIAP3 | c.1866C>T p.I622= | Silent (SNP) | VAF 21/92 reads (23%) | catalogued as rs377701660, COSV99136092; called by muse, mutect2, varscan2
- BEND2 | c.1398C>T p.S466= | Silent (SNP) | VAF 19/23 reads (83%) | catalogued as COSV101191673; called by muse, mutect2, varscan2
- C3orf22 | c.243G>C p.P81= | Silent (SNP) | VAF 16/136 reads (12%) | catalogued as COSV100559493, COSV100559530; called by muse, mutect2, varscan2
- C4orf19 | c.138C>T p.S46= | Silent (SNP) | VAF 92/193 reads (48%) | catalogued as COSV99448368; called by muse, mutect2, varscan2
- CACNA1G | c.3183G>T p.A1061= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV100660992, COSV61720699; called by muse, mutect2, varscan2
- CARD17 | c.168T>G p.A56= | Silent (SNP) | VAF 76/86 reads (88%) | catalogued as COSV100995138; called by muse, mutect2, varscan2
- CCDC136 | c.2796G>A p.L932= | Silent (SNP) | VAF 29/62 reads (47%) | catalogued as rs1384342120, COSV99921925; called by muse, mutect2, varscan2
- CCT8L2 | c.1584A>G p.T528= | Silent (SNP) | VAF 91/150 reads (61%) | catalogued as COSV100742499; called by muse, mutect2, varscan2
- CDH18 | c.37C>T p.L13= | Silent (SNP) | VAF 40/65 reads (62%) | catalogued as COSV99931228; called by muse, mutect2, varscan2
- COMMD1 | c.186T>C p.I62= | Silent (SNP) | VAF 32/69 reads (46%) | catalogued as COSV100311853; called by muse, mutect2, varscan2
- CRELD1 | c.450C>T p.P150= | Silent (SNP) | VAF 19/21 reads (90%) | catalogued as rs370830167; called by muse, mutect2, varscan2
- CYP46A1 | c.720C>A p.L240= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as COSV99952337; called by muse, varscan2
- DEGS2 | c.138G>A p.A46= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs769172630, COSV99979065; called by muse, mutect2, varscan2
- ENPP7 | c.693G>A p.A231= | Silent (SNP) | VAF 47/89 reads (53%) | catalogued as rs1317957260, COSV60387040; called by muse, mutect2, varscan2
- EPHA8 | c.348C>T p.G116= | Silent (SNP) | VAF 43/47 reads (91%) | catalogued as rs1407644622, COSV99384022; called by muse, mutect2, varscan2
- ESYT3 | c.2632C>T p.L878= | Silent (SNP) | VAF 30/196 reads (15%) | catalogued as COSV101272613; called by muse, mutect2, varscan2
- FCAR | c.846A>C p.T282= | Silent (SNP) | VAF 39/131 reads (30%) | catalogued as COSV100628926, COSV62031827; called by muse, mutect2, varscan2
- GDAP1L1 | c.600G>A p.E200= | Silent (SNP) | VAF 97/445 reads (22%) | catalogued as COSV100697434, COSV100697628; called by muse, mutect2, varscan2
- GSE1 | c.147G>T p.A49= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV99495895; called by muse, mutect2, varscan2
- IGSF9B | c.2589C>T p.A863= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as rs375548937; called by muse, mutect2, varscan2
- INHA | c.690C>A p.A230= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as COSV99215957; called by muse, mutect2, varscan2
- KDM3B | c.2076C>G p.L692= | Silent (SNP) | VAF 64/69 reads (93%) | catalogued as COSV100069043, COSV58695171; called by muse, mutect2, varscan2
- L1CAM | c.1572C>A p.P524= | Silent (SNP) | VAF 133/144 reads (92%) | catalogued as COSV100648816; called by muse, mutect2, varscan2
- LAMA2 | c.7425G>T p.T2475= | Silent (SNP) | VAF 28/45 reads (62%) | catalogued as COSV101369837, COSV70353508; called by muse, mutect2, varscan2
- LRRC4C | c.1200A>G p.K400= | Silent (SNP) | VAF 51/171 reads (30%) | catalogued as COSV99536571, COSV99539697; called by muse, mutect2, varscan2
- MAPK8IP3 | c.852C>A p.A284= | Silent (SNP) | VAF 31/123 reads (25%) | catalogued as COSV51716903, COSV99167595; called by muse, mutect2, varscan2
- MTR | c.3300T>C p.F1100= | Silent (SNP) | VAF 54/120 reads (45%) | catalogued as COSV100855176; called by muse, mutect2, varscan2
- MUC16 | c.18747T>C p.V6249= | Silent (SNP) | VAF 65/71 reads (92%) | catalogued as COSV101197393; called by muse, mutect2, varscan2
- NCAPD3 | c.1476G>C p.T492= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as COSV101599330; called by muse, mutect2, varscan2
- NDUFS1 | c.1095C>T p.T365= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as COSV99260177; called by muse, mutect2, varscan2
- NOX3 | c.186T>C p.N62= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as COSV99342550; called by muse, mutect2, varscan2
- NPAP1 | c.1588C>T p.L530= | Silent (SNP) | VAF 64/265 reads (24%) | catalogued as rs1416920511, COSV100274578, COSV61504390; called by muse, mutect2, varscan2
- OBSL1 | c.4101A>G p.T1367= | Silent (SNP) | VAF 16/27 reads (59%) | catalogued as COSV99522550; called by muse, mutect2, varscan2
- OIT3 | c.387T>C p.Y129= | Silent (SNP) | VAF 63/71 reads (89%) | catalogued as rs777823038, COSV100467515; called by muse, mutect2, varscan2
- OR10K2 | c.874T>C p.L292= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as COSV100149350; called by muse, mutect2, varscan2
- OR10K2 | c.873C>T p.S291= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as COSV100149351; called by muse, mutect2, varscan2
- OR2A12 | c.780C>A p.A260= | Silent (SNP) | VAF 144/290 reads (50%) | catalogued as COSV101283143; called by muse, mutect2, varscan2
- OR2T10 | c.276C>A p.I92= | Silent (SNP) | VAF 37/64 reads (58%) | catalogued as COSV57896350, COSV57898253; called by muse, mutect2, varscan2
- OR51A7 | c.396C>T p.Y132= | Silent (SNP) | VAF 52/80 reads (65%) | catalogued as rs1331330366, COSV100834567; called by muse, mutect2, varscan2
- OR8J1 | c.60T>C p.C20= | Silent (SNP) | VAF 69/80 reads (86%) | catalogued as COSV100274802; called by muse, mutect2, varscan2
- ORC1 | c.2355C>T p.F785= | Silent (SNP) | VAF 5/33 reads (15%) | called by muse, mutect2, varscan2
- PAPPA2 | c.1941C>A p.P647= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as COSV62789639; called by muse, mutect2, varscan2
- PDE11A | c.834G>T p.V278= | Silent (SNP) | VAF 44/150 reads (29%) | catalogued as COSV99610472; called by muse, mutect2, varscan2
- PKHD1L1 | c.9555G>A p.L3185= | Silent (SNP) | VAF 28/29 reads (97%) | catalogued as COSV101005078; called by muse, mutect2, varscan2
- PNMA8B | c.1068T>C p.V356= | Silent (SNP) | VAF 167/183 reads (91%) | catalogued as COSV100885260; called by muse, mutect2, varscan2
- PPP1R3A | c.2025T>C p.H675= | Silent (SNP) | VAF 79/349 reads (23%) | catalogued as COSV99491693; called by muse, mutect2, varscan2
- PRCC | c.693T>C p.P231= | Silent (SNP) | VAF 43/111 reads (39%) | catalogued as rs763973148, COSV99618359; called by muse, mutect2, varscan2
- PTX3 | c.573G>A p.K191= | Silent (SNP) | VAF 86/176 reads (49%) | catalogued as COSV99904737; called by muse, mutect2, varscan2
- RIMBP3 | c.1770G>A p.Q590= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs1440405159; called by muse, mutect2, varscan2
- RPUSD2 | c.747C>T p.F249= | Silent (SNP) | VAF 111/167 reads (66%) | catalogued as COSV100225055, COSV59766332; called by muse, mutect2, varscan2
- RTEL1 | c.3438G>C p.P1146= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV99422662; called by muse, mutect2, varscan2
- SFSWAP | c.87G>T p.G29= | Silent (SNP) | VAF 30/35 reads (86%) | catalogued as COSV99905673; called by muse, mutect2, varscan2
- SLC3A1 | c.636A>T p.I212= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as COSV99576717; called by muse, mutect2, varscan2
- SLITRK2 | c.492C>T p.I164= | Silent (SNP) | VAF 101/105 reads (96%) | catalogued as COSV100157238, COSV59424735; called by muse, mutect2, varscan2
- SMARCA4 | c.1794C>A p.A598= | Silent (SNP) | VAF 72/80 reads (90%) | catalogued as COSV100758000; called by muse, mutect2, varscan2
- STARD3NL | c.108G>A p.R36= | Silent (SNP) | VAF 24/131 reads (18%) | catalogued as COSV99151553; called by muse, mutect2, varscan2
- TCF25 | c.1587A>T p.A529= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs1410467116, COSV99642189; called by muse, mutect2, varscan2
- TMPRSS2 | c.690C>T p.A230= | Silent (SNP) | VAF 22/25 reads (88%) | catalogued as rs1399976174, COSV100150985; called by muse, mutect2, varscan2
- TRIM27 | c.9C>T p.S3= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs1275149839, COSV101019179; called by muse, mutect2, varscan2
- TRPC4 | c.1741T>C p.L581= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as COSV100155467; called by muse, mutect2, varscan2
- TRPV5 | c.655C>T p.L219= | Silent (SNP) | VAF 76/145 reads (52%) | catalogued as COSV54690783, COSV99519973; called by muse, mutect2, varscan2
- TTC21B | c.2364G>A p.K788= | Silent (SNP) | VAF 40/55 reads (73%) | catalogued as COSV104388428, COSV99691706; called by muse, mutect2, varscan2
- TTC25 | c.762G>C p.L254= | Silent (SNP) | VAF 104/211 reads (49%) | catalogued as COSV101102838, COSV66368929; called by muse, mutect2, varscan2
- TTN | c.20250A>G p.V6750= (on ENST00000591111; = p.V5823= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV60274483; called by muse, mutect2, varscan2
- TTN | c.11418C>A p.L3806= (on ENST00000591111; = p.L3760= on NM_003319.4) | Silent (SNP) | VAF 109/172 reads (63%) | catalogued as COSV100589305; called by muse, mutect2, varscan2
- TUBB4B | c.114G>A p.G38= | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as COSV100457575; called by muse, mutect2, varscan2
- UGT8 | c.630G>A p.L210= | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as rs749061254, COSV100178864; called by muse, mutect2, varscan2
- UTRN | c.4524G>A p.T1508= | Silent (SNP) | VAF 47/88 reads (53%) | catalogued as rs761437286, COSV100839387; called by muse, mutect2, varscan2
- ZNF703 | c.1596G>C p.L532= | Silent (SNP) | VAF 11/11 reads (100%) | catalogued as COSV100521664; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73846803 A>T | 5'Flank (SNP) | VAF 28/31 reads (90%) | called by muse, mutect2, varscan2
- HERC2P3 | n.1620G>T | RNA (SNP) | VAF 21/98 reads (21%) | called by muse, mutect2, varscan2
- IGKV1OR22-5 | n.82C>A | RNA (SNP) | VAF 33/187 reads (18%) | called by muse, mutect2, varscan2
- KIR3DL2 | chr19:54847198 C>A | 5'Flank (SNP) | VAF 93/425 reads (22%) | called by muse, mutect2, varscan2
- METTL16 | n.1007C>T | RNA (SNP) | VAF 22/22 reads (100%) | catalogued as rs373939145; called by muse, mutect2, varscan2
- OR2W5 | n.375A>G | RNA (SNP) | VAF 24/95 reads (25%) | called by muse, mutect2, varscan2
- SNX5 | c.51+5608C>T | Intron (SNP) | VAF 104/170 reads (61%) | catalogued as COSV100898951; called by muse, mutect2, varscan2
- SSPOP | n.2572A>T | RNA (SNP) | VAF 18/38 reads (47%) | catalogued as COSV100022009; called by muse, mutect2, varscan2
- SSPOP | n.12322C>T | RNA (SNP) | VAF 13/34 reads (38%) | catalogued as rs777260734, COSV100946897; called by muse, mutect2, varscan2
- SSPOP | n.14429G>T | RNA (SNP) | VAF 58/168 reads (35%) | catalogued as rs770806757, COSV100946898; called by muse, mutect2, varscan2
- TPK1 | c.185+15178C>T | Intron (SNP) | VAF 31/76 reads (41%) | catalogued as rs201334172; called by muse, mutect2, varscan2
